Somatic mutation profile of tumor specimen 0DIPL1 from CCDI case PBBVZL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.6 years (2,793 days).
Specimen 0DIPL1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b19e9d3e-e26b-4374-b731-3b106ccbe76a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b5ea5dc-9b68-4248-adbb-84e882b5c0ac

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, RNA 1, Splice Site 1, Translation Start Site 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 641/714 reads (90%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CILK1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 55/1140 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); catalogued as COSV63153565; called by muse, mutect2
- CLSTN1 | c.2809G>A p.E937K (on ENST00000377298 / NM_001009566.3; = p.E927K on NM_014944.4) | Missense Mutation (SNP) | VAF 911/1017 reads (90%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as rs142492603; called by muse, mutect2, varscan2
- DNMT3A | c.1840G>T p.D614Y | Missense Mutation (SNP) | VAF 102/1356 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV53036753, COSV53083794; called by muse, mutect2
- NOTCH3 | c.3088G>T p.G1030* | Nonsense Mutation (SNP) | VAF 100/1446 reads (7%) | catalogued as COSV54636073; called by muse, mutect2
- SH3BP5 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 60/1126 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs566469874; called by muse, mutect2
- TPTE | c.175G>A p.V59M (on ENST00000618007 / NM_199261.4; = p.V41M on NM_199259.4) | Missense Mutation (SNP) | VAF 433/5103 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs762316652; called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 76/2578 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- FAM184A | c.2251_2252dup p.V752Mfs*34 | Frame Shift Ins (INS) | VAF 529/1271 reads (42%) | called by mutect2, varscan2
- ITPR3 | c.6075+1G>T p.X2025_splice | Splice Site (SNP) | VAF 28/1186 reads (2%) | called by muse, mutect2
- PRLR | c.1666A>G p.N556D | Missense Mutation (SNP) | VAF 174/840 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TEX13D | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 34/758 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ZNF578 | c.1620A>T p.K540N | Missense Mutation (SNP) | VAF 38/1294 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- FUT2 | c.984G>A p.P328= | Silent (SNP) | VAF 520/1066 reads (49%) | catalogued as rs373270748; called by muse, mutect2, varscan2
- TTBK1 | c.3600G>A p.S1200= | Silent (SNP) | VAF 74/1286 reads (6%) | catalogued as rs985174914; called by muse, mutect2
- ZNF469 | c.696C>T p.A232= | Silent (SNP) | VAF 48/676 reads (7%) | called by muse, mutect2
- AL031768.2 | n.119C>T | RNA (SNP) | VAF 136/267 reads (51%) | catalogued as rs540786412; called by muse, mutect2, varscan2
- ARAP1 | c.1992+45T>G | Intron (SNP) | VAF 181/378 reads (48%) | called by muse, mutect2, varscan2
- DRAM2 | c.693+9G>A | Intron (SNP) | VAF 110/1957 reads (6%) | catalogued as rs751993216; called by muse, mutect2
